Somatic mutation profile of tumor specimen C3L-07611-02 (aliquot CPT0408500007) from CPTAC case C3L-07611, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.9 years (15,303 days).
Specimen C3L-07611-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56b17d01-4bb7-4cc9-a306-64af39764d21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07611-31 (Blood Derived Normal), aliquot CPT0408580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b54501e0-68e5-43e5-9445-d6a43f4e669c

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Intron 2, Splice Region 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTHFR | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 161/427 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769953411, COSV64878141; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL9 | c.2168A>G p.N723S | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52349501; called by muse, mutect2, varscan2
- CBL | c.1102T>G p.Y368D | Missense Mutation (SNP) | VAF 97/188 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50663560; called by muse, mutect2, varscan2
- CNGA3 | c.396C>T p.S132= | Splice Region (SNP) | VAF 49/407 reads (12%) | catalogued as rs1174225295, COSV55621819; called by muse, mutect2, varscan2
- ELF3 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 163/424 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs750329636, COSV62838337, COSV62839839; called by muse, mutect2, varscan2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- LPIN2 | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 168/389 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55243489; called by muse, mutect2, varscan2
- LRBA | c.6728A>G p.Y2243C | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63961312; called by muse, mutect2, varscan2
- LSM3 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs1484487436; called by muse, mutect2, varscan2
- OR2A14 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs761628504, COSV101376503; called by muse, mutect2, varscan2
- PCDHA12 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 238/564 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.116); catalogued as COSV56494202; called by muse, mutect2, varscan2
- SLC35D1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 180/471 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs750524219; called by muse, mutect2, varscan2
- TMC4 | c.309C>G p.H103Q (on ENST00000617472 / NM_001145303.3; = p.H97Q on NM_144686.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as rs904432620; called by muse, varscan2
- TMOD3 | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs143071324; called by muse, mutect2, varscan2
- TRAV9-1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 119/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770311900; called by muse, mutect2, varscan2
- WDR86 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 132/260 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs780957402, COSV57843471; called by muse, mutect2, varscan2
- ZCCHC12 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs946147207, COSV59570945; called by muse, mutect2, varscan2
- ZNF154 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 186/479 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs756506973, COSV70744760; called by muse, mutect2, varscan2
- ACSM2A | c.302G>C p.C101S (on ENST00000219054; = p.C22S on NM_001308169.2) | Missense Mutation (SNP) | VAF 50/488 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ACSM2B | c.302G>C p.C101S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARID1B | c.6639_6640del p.A2216Cfs*12 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- CHD3 | c.5252G>A p.G1751E (on ENST00000330494 / NM_001005273.3; = p.G1717E on NM_005852.4) | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF25 | c.646+2T>C p.X216_splice | Splice Site (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2
- NOS2 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKDC | c.7308G>T p.L2436F | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RBM33 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPANXN2 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 69/434 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- FBN3 | c.5964C>T p.S1988= | Silent (SNP) | VAF 53/212 reads (25%) | called by muse, mutect2, varscan2
- NT5C1B | c.546G>A p.S182= (on ENST00000359846 / NM_001199086.2; = p.S122= on NM_033253.4) | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs1363084909, COSV58394346; called by muse, mutect2, varscan2
- P3H2 | c.1248C>T p.N416= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs374730144; called by muse, mutect2, varscan2
- PCDHB8 | c.1479G>A p.P493= | Silent (SNP) | VAF 384/1655 reads (23%) | catalogued as COSV50757220; called by muse, mutect2, varscan2
- PLA2G4C | c.579C>T p.F193= | Silent (SNP) | VAF 87/214 reads (41%) | catalogued as rs566570586; called by muse, mutect2, varscan2
- ZNF699 | c.1797C>G p.P599= | Silent (SNP) | VAF 79/267 reads (30%) | called by muse, mutect2, varscan2
- EXD3 | c.-9G>A | 5'UTR (SNP) | VAF 94/259 reads (36%) | catalogued as rs762538772; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48032C>G | Intron (SNP) | VAF 61/127 reads (48%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23970C>A | Intron (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- WT1 | chr11:32440038 C>T | 5'Flank (SNP) | VAF 43/168 reads (26%) | called by muse, mutect2, varscan2
